Gene-level copy-number profile of tumor specimen TCGA-L9-A444-01A from TCGA case TCGA-L9-A444, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.8 years (22,202 days).
Specimen TCGA-L9-A444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.cef12e73-9728-40de-8cdc-7187dbc395f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L9-A444-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a04d2f15-8f1b-4c7f-852e-195d2a124265

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 11,875; copy number 2: 31,493; copy number 3: 8,436; copy number 4: 6,480; copy number 5: 869; copy number 6: 427; copy number 8: 124; copy number 10: 27; copy number 12: 18; copy number 17: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L9-A444-01A-21D-A24C-01): tumor purity 0.37, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:27,638,483–28,429,490, 19 genes: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1.
- chr19:28,437,060–28,535,277, 1 gene (within-gene range 0–2): AC005381.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,509 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–156,933,094, 637 genes, copy number 5–8 (broad region; genes not listed).
- chr1:156,936,131–156,936,244, 1 gene, copy number 5: MIR765.
- chr1:159,466,321–162,370,475, 133 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr6:44,809,317–60,723,898, 207 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:60,826,185–60,826,533, 1 gene, copy number 5: AL512427.1.
- chr7:42,909,273–52,897,807, 169 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:54,542,325–55,862,755, 37 genes, copy number 6: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr11:76,800,364–78,574,874, 45 genes, copy number 5 (within-gene range 2–5): AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2.
- chr13:105,690,429–111,115,678, 78 genes, copy number 6–8 (broad region; genes not listed).
- chr13:111,122,652–111,153,171, 3 genes, copy number 8: ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1.
- chr14:30,622,291–31,457,441, 22 genes, copy number 10 (within-gene range 2–10): SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1.
- chr14:33,924,227–36,656,163, 68 genes, copy number 5–17 (within-gene range 2–17) (broad region; genes not listed).
- chr17:64,936,485–67,785,293, 56 genes, copy number 5–6: AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1, AMZ2P1, GNA13, AC037487.2, RGS9, AC060771.1, LINC02563, AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH, RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41.
- chr17:69,414,697–70,128,859, 9 genes, copy number 5 (within-gene range 2–5): MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028.
- chr18:1,883,524–2,489,426, 1 gene, copy number 6 (within-gene range 4–6): AP005230.1.
- chr18:2,506,628–3,478,978, 37 genes, copy number 6: AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,656,282, 5 genes, copy number 6: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.

Autosomal genes at a single copy (total copy number 1): 11,875. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
